Gene-level copy-number profile of tumor specimen TCGA-D5-5540-01A from TCGA case TCGA-D5-5540, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIA; Age at diagnosis: 73.8 years (26,972 days).
Specimen TCGA-D5-5540-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.81e8600a-2dd0-4603-9941-556b80b4b33f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D5-5540-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fc658941-2773-45cd-9877-884058d1b32d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 15,176; copy number 2: 38,812; copy number 3: 4,919; copy number 4: 902.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D5-5540-01A-01D-1649-01): tumor purity 0.89, ploidy 1.9, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:64,745,095–65,067,754, 4 genes (within-gene range 0–1): RAVER2, JAK1, AL606517.2, AL606517.1.
- chr14:48,819,360–49,077,505, 2 genes: AL512360.1, AL110505.1.
- chr14:85,385,927–85,420,550, 2 genes: LINC02329, LINC00911.
- chr18:36,297,714–36,780,055, 1 gene (within-gene range 0–1): FHOD3.
- chr18:36,777,647–36,829,216, 1 gene: TPGS2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 12,790. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
